Somatic mutation profile of tumor specimen TCGA-CL-5918-01A (aliquot TCGA-CL-5918-01A-11D-1657-10) from TCGA case TCGA-CL-5918, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CL-5918-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6aa351be-bb1d-4058-a7d6-a09661a38c63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CL-5918-10A (Blood Derived Normal), aliquot TCGA-CL-5918-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dc7691b-e3df-470f-b2d9-464de55a8b33

The open-access MAF lists 131 somatic variants for this specimen: 100 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 29, Nonsense Mutation 8, Splice Site 3, Frame Shift Del 1, In Frame Del 1, Intron 1, Splice Region 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 25/376 reads (7%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 82/239 reads (34%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, varscan2
- GNE | c.622C>T p.R208C (on ENST00000396594 / NM_001128227.3; = p.R177C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs539332585, CM025974, COSV64951948, COSV64952559; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT13 | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV57764430; called by muse, mutect2, varscan2
- ACVR1 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55121112; called by muse, mutect2, varscan2
- APC | c.3980C>A p.S1327* | Nonsense Mutation (SNP) | VAF 74/116 reads (64%) | catalogued as COSV57323640, COSV57335489, COSV57371230; called by muse, mutect2, varscan2
- ARHGEF9 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99491985; called by muse, mutect2
- BEST2 | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.579); catalogued as COSV99244479; called by muse, mutect2, varscan2
- BLK | c.1181-1G>A p.X394_splice | Splice Site (SNP) | VAF 26/92 reads (28%) | catalogued as rs922956428, COSV52054576; called by muse, mutect2, varscan2
- BOP1 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs982920247; called by muse, mutect2, varscan2
- CACNA1G | c.3889C>T p.R1297C | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376210592; called by muse, mutect2, varscan2
- CALB2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs748994795, COSV56938432; called by muse, mutect2, varscan2
- CCDC106 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs371292659; called by muse, mutect2, varscan2
- CHAMP1 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as COSV63522380; called by muse, mutect2, varscan2
- CHIT1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs142999142, COSV55148192, COSV99705154; called by muse, mutect2, varscan2
- CHTF18 | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as rs2294453, COSV50210449; called by muse, mutect2, varscan2
- CLEC2L | c.406G>C p.A136P | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV70691216; called by muse, mutect2, varscan2
- COG5 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 61/558 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99772454; called by mutect2, varscan2
- COL7A1 | c.5956G>A p.E1986K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs144208360; called by muse, mutect2, varscan2
- CPE | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV101291619, COSV68580469; called by muse, mutect2
- CSMD1 | c.10312G>A p.G3438S (on ENST00000520002; = p.G3437S on NM_033225.6) | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100149869; called by mutect2, varscan2
- CSMD2 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1356557694, COSV53912898; called by muse, mutect2, varscan2
- CSPG4 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs140241379; called by muse, mutect2
- CYP27C1 | c.821A>C p.Y274S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757287610, COSV58866855; called by muse, mutect2, varscan2
- DEPDC7 | c.1147C>T p.R383* (on ENST00000241051 / NM_001077242.2; = p.R374* on NM_139160.2) | Nonsense Mutation (SNP) | VAF 108/253 reads (43%) | catalogued as rs1376367564, COSV99572778; called by muse, varscan2
- DHX38 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs779025493, COSV51698011; called by muse, mutect2, varscan2
- DNAH7 | c.228T>A p.S76R | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV56765265; called by muse, mutect2, varscan2
- DPH2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV52543483; called by muse, mutect2, varscan2
- EHD3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1366749439, COSV59030559; called by muse, mutect2, varscan2
- ERAP1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57087668; called by muse, mutect2, varscan2
- EXOC3L2 | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.108); catalogued as rs1028111777, COSV99374562; called by muse, mutect2
- FAM47B | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1003154042, COSV61453303, COSV61453412; called by muse, mutect2, varscan2
- FAT1 | c.6499G>C p.E2167Q | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV71673957; called by muse, mutect2
- FLG | c.6929C>G p.S2310C | Missense Mutation (SNP) | VAF 196/654 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV100911687, COSV64239386; called by muse, varscan2
- FSIP2 | c.17800A>T p.I5934F | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58086137; called by muse, mutect2, varscan2
- FZD9 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1554563256, COSV60670186; called by muse, mutect2
- GABBR2 | c.1903G>C p.A635P | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.697); catalogued as COSV52303210, COSV52304053; called by muse, mutect2, varscan2
- GLDC | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201135624; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- HTR3E | c.1189G>A p.E397K (on ENST00000415389 / NM_001256613.1; = p.E412K on NM_182589.2) | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.251); catalogued as COSV100094249; called by muse, mutect2, varscan2
- IGSF9B | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759057342, COSV58067680; called by muse, mutect2, varscan2
- ITGA9 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369201522; called by muse, mutect2, varscan2
- KCNC4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV63925631; called by muse, mutect2, varscan2
- LAMA5 | c.2600A>T p.Y867F | Missense Mutation (SNP) | VAF 87/128 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.19); catalogued as COSV53360351; called by muse, mutect2, varscan2
- LATS1 | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53591003, COSV53591320; called by muse, mutect2, varscan2
- LHX4 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs765008063, CM1210491, COSV55375531; called by muse, mutect2, varscan2
- LILRA2 | c.1355G>A p.R452H (on ENST00000391738 / NM_001130917.3; = p.R435H on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs199988092, COSV52191718; called by muse, mutect2, varscan2
- LRRFIP2 | c.554A>T p.K185M | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV60867732; called by muse, mutect2, varscan2
- LTBP1 | c.4367C>T p.T1456M (on ENST00000404816 / NM_206943.4; = p.T1130M on NM_000627.4) | Missense Mutation (SNP) | VAF 124/259 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as rs374132100, COSV55379249; called by muse, mutect2, varscan2
- MAGEC1 | c.1290T>G p.S430R | Missense Mutation (SNP) | VAF 53/764 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.403); catalogued as COSV99595950; called by muse, mutect2
- MFSD12 | c.1023+1G>A p.X341_splice | Splice Site (SNP) | VAF 24/76 reads (32%) | catalogued as rs775309500, COSV61535543; called by mutect2, varscan2
- MIOS | c.1417A>C p.N473H | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV60768458; called by muse, mutect2
- MKRN3 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs745694373, COSV58808917; called by muse, mutect2, varscan2
- MPZL3 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54053299; called by muse, mutect2, varscan2
- MRAP2 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57632494; called by muse, mutect2, varscan2
- NAV3 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV57069982; called by muse, mutect2, varscan2
- NBEA | c.7864C>T p.R2622* | Nonsense Mutation (SNP) | VAF 94/175 reads (54%) | catalogued as COSV59785030; called by muse, mutect2, varscan2
- NECTIN4 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 40/169 reads (24%) | catalogued as rs1450188245, COSV63512739; called by muse, mutect2, varscan2
- NKX3-2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101219921; called by muse, mutect2, varscan2
- NKX6-2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV100888351; called by muse, mutect2, varscan2
- OR52A5 | c.437T>G p.I146S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100263491; called by muse, mutect2
- PCDHGA8 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV53949255; called by muse, mutect2, varscan2
- PKD1L1 | c.2197G>A p.V733M | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372022624; called by muse, mutect2, varscan2
- PLXNA2 | c.4667G>A p.R1556H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs200636622; called by muse, mutect2, varscan2
- PNCK | c.635T>C p.F212S (on ENST00000340888 / NM_001366975.1; = p.F295S on NM_001039582.3) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100562365; called by muse, mutect2
- PON3 | c.367+2T>C p.X123_splice | Splice Site (SNP) | VAF 162/520 reads (31%) | catalogued as COSV55699335; called by muse, mutect2, varscan2
- PSD | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs774485946, COSV50042597; called by muse, mutect2, varscan2
- PTPN5 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1037962955, COSV62125787; called by muse, mutect2, varscan2
- RAB3GAP1 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 107/396 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99921296, COSV99921417; called by muse, mutect2, varscan2
- RBMS2 | c.735C>T p.G245= | Splice Region (SNP) | VAF 36/98 reads (37%) | catalogued as rs148057149; called by muse, mutect2, varscan2
- RGL3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs149175134; called by muse, mutect2, varscan2
- ROBO4 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs748069633, COSV100127663; called by muse, mutect2
- RRAS2 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV56330350; called by muse, mutect2, varscan2
- RRP8 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs763957188, COSV54449610; called by muse, mutect2, varscan2
- RUNX1T1 | c.796C>T p.R266* (on ENST00000265814 / NM_001198628.1; = p.R239* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 174/338 reads (51%) | catalogued as COSV56147139; called by muse, mutect2, varscan2
- RUNX3 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58243891; called by muse, mutect2, varscan2
- RYR2 | c.14702T>G p.V4901G | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV63686043; called by muse, mutect2
- SDC3 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767402418, COSV59579449; called by muse, mutect2, varscan2
- SGO2 | c.3760T>G p.F1254V | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV63415445; called by muse, mutect2
- SH2B2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.291); catalogued as rs782055416, COSV100159464; called by muse, mutect2, varscan2
- SLC27A5 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757190701, COSV54019579; called by muse, mutect2, varscan2
- SOHLH2 | c.410C>A p.T137K | Missense Mutation (SNP) | VAF 21/381 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100499436; called by muse, mutect2
- SPINK2 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV50534268; called by muse, mutect2, varscan2
- STAP1 | c.859A>T p.K287* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as COSV99609522; called by muse, mutect2
- THSD7A | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1320096867, COSV70261585; called by muse, mutect2, varscan2
- TPO | c.1851C>A p.S617R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as rs368276909, COSV100221500; called by muse, mutect2, varscan2
- TTN | c.55355G>T p.G18452V (on ENST00000591111; = p.G11028V on NM_003319.4) | Missense Mutation (SNP) | VAF 16/200 reads (8%) | PolyPhen probably damaging (1); catalogued as COSV60066433; called by muse, mutect2
- TTN | c.42688C>A p.Q14230K (on ENST00000591111; = p.Q6806K on NM_003319.4) | Missense Mutation (SNP) | VAF 65/218 reads (30%) | PolyPhen probably damaging (0.979); catalogued as COSV60066480; called by muse, mutect2, varscan2
- USP37 | c.2329G>T p.D777Y | Missense Mutation (SNP) | VAF 41/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99294572; called by muse, mutect2
- XRRA1 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV58497884; called by muse, mutect2
- YPEL1 | c.107T>A p.L36H | Missense Mutation (SNP) | VAF 96/276 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59756886; called by muse, mutect2, varscan2
- ZNF154 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1352766666, COSV70745060; called by muse, mutect2, varscan2
- ZNF500 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs1248312526, COSV99556389; called by muse, mutect2
- ZNF574 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs1188692563, COSV55903419; called by muse, mutect2, varscan2
- ZNF574 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs757760817, COSV55903435; called by muse, mutect2, varscan2
- DDHD2 | c.1556_1561del p.K519_R520del | In Frame Del (DEL) | VAF 52/316 reads (16%) | called by mutect2, pindel, varscan2
- PRAMEF5 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by mutect2, varscan2
- SHROOM4 | c.3384_3391delinsACAGCAGCAGCAGAAGCAACGGG p.K1129_Q1131delinsQQQQKQRE | In Frame Ins (INS) | VAF 6/34 reads (18%) | called by pindel, varscan2*
- SNX7 | c.647_648del p.S216Ffs*28 | Frame Shift Del (DEL) | VAF 60/202 reads (30%) | called by pindel, varscan2
- ZBED9 | c.3422A>G p.E1141G | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- COL14A1 | c.4431C>A p.G1477= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV99918098, COSV99919657; called by muse, mutect2, varscan2
- COL4A3 | c.1311G>A p.P437= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as rs369557944; called by muse, mutect2, varscan2
- DAPK1 | c.2301G>A p.P767= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs371530974; called by muse, mutect2, varscan2
- FGF17 | c.87G>A p.P29= | Silent (SNP) | VAF 58/197 reads (29%) | catalogued as rs552877908, COSV63925533; called by muse, mutect2, varscan2
- GARNL3 | c.423T>C p.I141= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV59226359; called by muse, mutect2
- GRK3 | c.1098G>A p.T366= | Silent (SNP) | VAF 51/163 reads (31%) | catalogued as rs985300648, COSV60795853; called by muse, mutect2, varscan2
- HRNR | c.6594C>T p.H2198= | Silent (SNP) | VAF 30/216 reads (14%) | catalogued as rs534099891, COSV64254199; called by muse, varscan2
- HTR3B | c.954T>G p.A318= | Silent (SNP) | VAF 40/391 reads (10%) | catalogued as COSV99492063; called by muse, mutect2
- IQCN | c.1302G>C p.L434= | Silent (SNP) | VAF 78/192 reads (41%) | catalogued as COSV66574384; called by muse, mutect2, varscan2
- IRS4 | c.312C>T p.D104= | Silent (SNP) | VAF 79/116 reads (68%) | catalogued as COSV64533854; called by muse, mutect2, varscan2
- KNG1 | c.594C>T p.T198= | Silent (SNP) | VAF 77/193 reads (40%) | catalogued as rs148661420, COSV53977880; called by muse, mutect2, varscan2
- LANCL3 | c.69T>C p.C23= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs782035115; called by muse, mutect2
- MAGEB4 | c.246A>G p.K82= | Silent (SNP) | VAF 69/207 reads (33%) | catalogued as COSV100854722; called by muse, mutect2, varscan2
- MYO6 | c.99C>G p.P33= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV64119045; called by muse, mutect2
- NFX1 | c.1090T>C p.L364= | Silent (SNP) | VAF 10/249 reads (4%) | called by muse, mutect2
- OR2B3 | c.48C>A p.G16= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs753171100, COSV101013808; called by muse, mutect2, varscan2
- PCDHGA2 | c.1947C>T p.H649= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs769573354, COSV53965443; called by muse, mutect2
- PDE10A | c.1341C>T p.Y447= | Silent (SNP) | VAF 13/162 reads (8%) | catalogued as rs780011165, COSV100605243; called by muse, mutect2
- POM121L12 | c.594C>T p.F198= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs1398358196, COSV68692268; called by muse, mutect2, varscan2
- PSEN2 | c.414C>T p.S138= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs747738607, COSV60915335; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFX7 | c.4002A>G p.Q1334= (on ENST00000559447 / NM_001368074.1; = p.Q1431= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 127/188 reads (68%) | catalogued as rs776565931, COSV57963456; called by muse, mutect2, varscan2
- SLC39A13 | c.603G>A p.P201= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs372236399; called by muse, varscan2
- SRCAP | c.4386C>T p.P1462= | Silent (SNP) | VAF 93/235 reads (40%) | catalogued as rs780574752, COSV99350491; called by muse, mutect2, varscan2
- TRRAP | c.10053G>A p.A3351= (on ENST00000359863 / NM_001244580.1; = p.A3322= on NM_003496.3) | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as rs761352412, COSV62840959, COSV62850350; called by muse, mutect2, varscan2
- TULP1 | c.138G>A p.T46= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV57691682; called by muse, mutect2, varscan2
- VSIG10 | c.534C>G p.G178= | Silent (SNP) | VAF 53/141 reads (38%) | catalogued as COSV63653372; called by muse, mutect2, varscan2
- YWHAE | c.471T>C p.D157= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1357591809, COSV51982565; called by muse, mutect2, varscan2
- ZNF518B | c.627G>T p.T209= | Silent (SNP) | VAF 77/188 reads (41%) | catalogued as COSV58722422, COSV58722687; called by muse, mutect2, varscan2
- ZNF676 | c.966C>A p.S322= (on ENST00000650058; = p.S290= on NM_001001411.3) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV68093089; called by muse, mutect2, varscan2
- BDNF | c.-21-15631G>T | Intron (SNP) | VAF 57/133 reads (43%) | catalogued as COSV59235325; called by muse, mutect2, varscan2
- MIR323A | n.22T>C | RNA (SNP) | VAF 72/124 reads (58%) | called by muse, mutect2, varscan2
